TCGA case TCGA-91-7771 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: ABS - IUPUI. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c0fdb152-25d2-404b-bec7-a43ece381f5b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 62.8 years (22,926 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 77 days; Days to treatment end: 156 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Thymoma, NOS: ICD-O-3 morphology code: 8580/1; Tissue or organ of origin: Thymus; Classification of tumor: Synchronous primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 492 days (1.3 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 31.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 75; Tobacco smoking quit year: 2011.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-91-7771-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 3; Intermediate dimension: 0.9; Shortest dimension: 0.6.
  Slide TCGA-91-7771-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 61; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
  Slide TCGA-91-7771-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 61; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-91-7771-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tobacco smoking history indicator: 4; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Pulmonary function test indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy histological type: thymoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous thymoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 492 days; disease-specific survival: no event (censored), 492 days; disease-free interval: no event (censored), 492 days; progression-free interval: no event (censored), 492 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-91-7771-01A-11D-2166-01): tumor purity 0.32, ploidy 5, whole-genome doublings 2.
